CCDI case PBBHGT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/27a259ec-80de-4e0a-8986-4fa0d2c47465

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 7.7 years (2,799 days).

Biospecimens (3 samples)
- Sample 0D8BV8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D8BV9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D8BVB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
